Somatic mutation profile of tumor specimen TCGA-L5-A43J-01A (aliquot TCGA-L5-A43J-01A-12D-A247-09) from TCGA case TCGA-L5-A43J, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-L5-A43J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94c6a5ab-0655-4452-917a-5f868183601d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A43J-11A (Solid Tissue Normal), aliquot TCGA-L5-A43J-11A-11D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b6b5f4b-2c8d-4ff3-aad3-c2afc4da120a

The open-access MAF lists 847 somatic variants for this specimen: 655 protein-altering or splice-affecting, 179 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 445, Silent 179, Frame Shift Del 132, Frame Shift Ins 31, In Frame Del 20, Nonsense Mutation 17, Splice Site 10, Intron 7, RNA 3, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (750 of 847; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- AGL | c.3911dup p.N1304Kfs*7 | Frame Shift Ins (INS) | VAF 27/53 reads (51%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.5351dup p.N1784Kfs*3 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | catalogued as rs80359507; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CSNK2A1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs869312845, COSV53935145; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.1229del p.P410Rfs*30 (on ENST00000359125 / NM_172107.4; = p.P400Rfs*12 on NM_004518.6) | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs886041339, CD094786; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.15536G>A p.R5179H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs267607237, CM105472, COSV56428259, COSV56447076, COSV56496109; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707dup | Intron (INS) | VAF 14/43 reads (33%) | catalogued as rs747392139; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- RPE65 | c.1067dup p.N356Kfs*9 | Frame Shift Ins (INS) | VAF 18/59 reads (31%) | catalogued as rs281865520; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- RYR1 | c.4405C>T p.R1469W | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200546266, CM105854, COSV62097131; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 23/56 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 35/80 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as rs746497630; called by mutect2, varscan2
- AARS2 | c.2607del p.T871Lfs*13 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs771808127, COSV55113098; called by mutect2, pindel, varscan2
- ABCA4 | c.3420C>A p.C1140* | Nonsense Mutation (SNP) | VAF 56/96 reads (58%) | catalogued as CM145309; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCD2 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs572444310; called by muse, mutect2, varscan2
- ABHD18 | c.914G>A p.R305H (on ENST00000398965 / NM_001039717.2; = p.R212H on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as rs767049484; called by muse, varscan2
- ABR | c.2479G>A p.V827I (on ENST00000302538 / NM_021962.5; = p.V790I on NM_001092.5) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs111816976; called by muse, varscan2
- AC126283.2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1350193194, COSV67098235; called by muse, mutect2, varscan2
- ACOX3 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs528832606, COSV62710694; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | catalogued as rs767549806; called by mutect2, varscan2
- ADAMTS15 | c.2176C>A p.L726M | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54509695; called by muse, mutect2, varscan2
- ADAP2 | c.503A>C p.K168T | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58295505; called by muse, mutect2, varscan2
- ADGRB3 | c.3212G>T p.G1071V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766550347, COSV99484449; called by muse, mutect2, varscan2
- ADH7 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367907552; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 46/84 reads (55%) | catalogued as rs761350619; called by mutect2, varscan2
- AIMP2 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.809); catalogued as rs766467029; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKT1 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62572953; called by muse, mutect2
- AL117348.2 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | PolyPhen benign (0); catalogued as rs145906534, COSV55282574; called by muse, mutect2, varscan2
- AL592490.1 | c.1256T>C p.V419A | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV101308123; called by muse, mutect2, varscan2
- ALOX12B | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs141010860; called by muse, mutect2, varscan2
- AMY1C | c.938A>T p.N313I | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200267405, COSV100915248, COSV64407089; called by muse, mutect2, varscan2
- ANKH | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs772363889, COSV52481188; called by muse, mutect2, varscan2
- ANKRD26 | c.2125A>G p.M709V | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs370486658; called by muse, mutect2, varscan2
- ANKRD28 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs748420293; called by muse, mutect2, varscan2
- AP1M1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs1414106796, COSV52229061; called by muse, mutect2, varscan2
- APOB | c.538-2A>G p.X180_splice | Splice Site (SNP) | VAF 55/108 reads (51%) | catalogued as COSV51948115; called by muse, mutect2, varscan2
- APPL1 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769152501; called by muse, mutect2, varscan2
- ARHGAP21 | c.3316A>G p.R1106G | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199641044; called by muse, mutect2, varscan2
- ARPC5 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs369978826; called by muse, mutect2, varscan2
- ARSI | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1478314305; called by muse, mutect2, varscan2
- ARVCF | c.2015C>T p.T672M | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1432233669; called by muse, mutect2, varscan2
- ASAP2 | c.1111+1G>A p.X371_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | catalogued as COSV55638714; called by muse, varscan2
- ATRNL1 | c.2648C>T p.A883V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs140372621; called by muse, mutect2, varscan2
- BIN1 | c.550dup p.Q184Pfs*16 | Frame Shift Ins (INS) | VAF 24/56 reads (43%) | catalogued as rs746044582; called by mutect2, varscan2
- BOD1L1 | c.2440A>G p.I814V | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs1012143127; called by muse, mutect2, varscan2
- BPIFB1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374640604; called by muse, mutect2, varscan2
- BTBD9 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs150015110, COSV58426603; called by muse, mutect2, varscan2
- BTRC | c.560G>A p.R187Q (on ENST00000370187 / NM_033637.4; = p.R151Q on NM_003939.5) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs747705989; called by muse, mutect2, varscan2
- C1orf127 | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs777328651; called by muse, mutect2, varscan2
- C1orf159 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs147871493; called by muse, mutect2, varscan2
- C2orf42 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as rs1404103358; called by muse, mutect2, varscan2
- C6 | c.828dup p.S277Efs*15 | Frame Shift Ins (INS) | VAF 14/90 reads (16%) | catalogued as rs372345940; called by mutect2, varscan2
- C6orf118 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs140500230; called by muse, mutect2, varscan2
- CACNA1B | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs756199654; called by muse, mutect2, varscan2
- CACNG3 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs1488719446, COSV50086419; called by muse, mutect2, varscan2
- CALCOCO1 | c.1985G>A p.R662H | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs775292722; called by muse, mutect2, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CARS1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1396843622, COSV53453537; called by muse, mutect2
- CATIP | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759205178; called by muse, mutect2, varscan2
- CCDC110 | c.1706T>C p.I569T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.796); catalogued as rs1172530457; called by muse, mutect2, varscan2
- CCDC130 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs377239448; called by muse, mutect2, varscan2
- CCDC148 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs748550649; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC18 | c.1802dup p.N601Kfs*13 (on ENST00000343253 / NM_001306076.1; = p.N602Kfs*13 on NM_206886.4) | Frame Shift Ins (INS) | VAF 11/53 reads (21%) | catalogued as rs1557640875; called by mutect2, pindel, varscan2
- CCDC180 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs142121305; called by muse, mutect2, varscan2
- CCDC42 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs752677099; called by muse, mutect2, varscan2
- CCL14 | c.137G>A p.R46H (on ENST00000618404 / NM_032963.4; = p.R62H on NM_032962.4) | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs144903710; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as rs761073142; called by mutect2, varscan2
- CD1A | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.83); catalogued as COSV56861601; called by muse, mutect2, varscan2
- CDC40 | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV99070327; called by muse, mutect2, varscan2
- CDH11 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs374274441, COSV99217594; called by muse, varscan2
- CDH11 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99216691; called by muse, varscan2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs749463697; called by mutect2, pindel, varscan2
- CEP170B | c.2557C>T p.R853W (on ENST00000453495; = p.R782W on NM_015005.3) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs758162711, COSV69026079; called by muse, mutect2, varscan2
- CFAP74 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1380870743, COSV54564656; called by muse, mutect2, varscan2
- CHRDL2 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs200667288, COSV55223143; called by muse, mutect2, varscan2
- CIDEA | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs374773954; called by muse, varscan2
- CLCN7 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs937106092, CM099584; called by muse, mutect2, varscan2
- CLIC5 | c.1124G>A p.R375Q (on ENST00000185206 / NM_001370649.1; = p.R216Q on NM_016929.5) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs372300556; called by muse, mutect2, varscan2
- CNOT3 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs764340197; called by muse, mutect2, varscan2
- CNTNAP5 | c.2820G>A p.M940I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs780606060, COSV101444208; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs374805044; called by mutect2, varscan2
- COIL | c.485dup p.N162Kfs*6 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | catalogued as rs769265872; called by mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL4A3 | c.1363G>T p.G455C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1414055; called by muse, mutect2
- COL5A1 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as rs770761070, COSV65668640; called by mutect2, varscan2
- CPEB2 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs374594133; called by muse, mutect2, varscan2
- CPSF1 | c.884del p.P295Rfs*53 | Frame Shift Del (DEL) | VAF 9/93 reads (10%) | catalogued as COSV100574741; called by mutect2, pindel
- CRAT | c.495del p.K166Sfs*5 | Frame Shift Del (DEL) | VAF 34/97 reads (35%) | catalogued as rs772054700, COSV58879005; called by mutect2, pindel, varscan2
- CSMD3 | c.9073C>T p.R3025C (on ENST00000297405 / NM_001363185.1; = p.R2856C on NM_052900.3) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs775065918, COSV52095077; called by muse, mutect2, varscan2
- CST4 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 39/212 reads (18%) | catalogued as rs767756120; called by mutect2, pindel, varscan2
- CSTF2T | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs376475408; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.215); catalogued as rs1221156787; called by muse, mutect2, varscan2
- CUX1 | c.2591G>T p.R864L | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs748035791; called by muse, mutect2, varscan2
- CUX2 | c.1891C>T p.R631W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761088744; called by muse, varscan2
- CYP4Z1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs778352142; called by muse, mutect2, varscan2
- DCHS1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs374740842, COSV100201706; called by muse, mutect2, varscan2
- DCST1 | c.174del p.L59Sfs*4 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | catalogued as rs746224810; called by pindel, varscan2
- DDX11 | c.2516G>A p.R839H (on ENST00000545668 / NM_152438.2; = p.V791I on NM_004399.3) | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.188); catalogued as rs755347093; called by muse, mutect2, varscan2
- DENND4B | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs766715207, COSV63411311; called by muse, mutect2, varscan2
- DENND5A | c.3350A>G p.N1117S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs767982228; called by muse, mutect2, varscan2
- DNAH10 | c.13214G>A p.R4405Q (on ENST00000409039; = p.R4344Q on NM_207437.3) | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765072673, COSV53019875; called by muse, mutect2, varscan2
- DNAH5 | c.5718G>A p.M1906I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1324133724, COSV54215396; called by muse, mutect2
- DNAJC19 | c.129+1G>A p.X43_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as rs1003922271; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 28/44 reads (64%) | catalogued as rs782552436; called by mutect2, varscan2
- DOK1 | c.245del p.P82Lfs*76 | Frame Shift Del (DEL) | VAF 43/135 reads (32%) | catalogued as rs750803751; called by mutect2, pindel, varscan2
- DUS2 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as rs756355529; called by muse, mutect2, varscan2
- DUSP26 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 32/54 reads (59%) | catalogued as rs750549145; called by muse, mutect2, varscan2
- EGFLAM | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs200259259, COSV100380738, COSV59297476; called by muse, mutect2, varscan2
- EGFR | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs760471492, COSV51794659; called by muse, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs751148694; called by mutect2, varscan2
- ENOX2 | c.655C>T p.R219C (on ENST00000338144 / NM_001382520.1; = p.R190C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/93 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762779115, COSV57648899; called by muse, mutect2, varscan2
- ERCC6 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs755721992, COSV100876380; called by muse, mutect2, varscan2
- ERN2 | c.466del p.R156Afs*43 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs760310462, COSV56838101; called by mutect2, pindel, varscan2
- ERO1B | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs974034616, COSV59242434; called by muse, mutect2, varscan2
- EWSR1 | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs535564625, COSV58422816; called by muse, varscan2
- FAM153B | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs1167821311; called by mutect2, varscan2
- FBLN2 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs1272556761, COSV55480844; called by muse, mutect2, varscan2
- FBXL7 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs369795247; called by muse, mutect2, varscan2
- FBXO10 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); catalogued as rs1182558248; called by muse, mutect2, varscan2
- FGF23 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs1206151319, COSV52977264; called by muse, mutect2, varscan2
- FLNC | c.7922G>A p.R2641Q | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs760857362, COSV99972485; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT2 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV67528992; called by muse, mutect2
- FMOD | c.929del p.P310Qfs*31 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV61610636; called by mutect2, pindel, varscan2
- FNDC3B | c.3165del p.T1056Pfs*7 | Frame Shift Del (DEL) | VAF 25/88 reads (28%) | catalogued as rs769012096; called by mutect2, pindel, varscan2
- FNDC3B | c.3227C>T p.T1076M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as rs752282685, COSV61041819, COSV61049746; called by muse, mutect2, varscan2
- FNDC8 | c.832C>A p.L278M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.3); catalogued as COSV99338622; called by muse, mutect2
- FOLR1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100398586; called by muse, mutect2, varscan2
- FOXB2 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774683505; called by muse, mutect2, varscan2
- FOXP3 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1557115601, COSV100873061; called by muse, mutect2, varscan2
- FZD6 | c.2033G>A p.S678N | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1465708211, COSV62472081; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GADD45GIP1 | c.553_555del p.K185del | In Frame Del (DEL) | VAF 36/107 reads (34%) | catalogued as rs777674072; called by pindel, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs763679060; called by mutect2, varscan2
- GPC2 | c.1666del p.A556Hfs*31 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | catalogued as rs753572388; called by mutect2, pindel, varscan2
- GPER1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs775268794; called by muse, mutect2, varscan2
- GPR153 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs777963528, COSV100928577, COSV64938699; called by muse, mutect2, varscan2
- GPR32 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.958); catalogued as COSV54515316; called by muse, mutect2, varscan2
- GPR37 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs200937236, COSV58258381; called by muse, mutect2, varscan2
- GPT | c.1419del p.L474Wfs*11 | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | catalogued as COSV52953289; called by mutect2, pindel, varscan2
- GRAMD4 | c.813del p.X271_splice | Splice Site (DEL) | VAF 18/61 reads (30%) | catalogued as rs1486468569; called by mutect2, pindel, varscan2
- GRB10 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs761493243, COSV60010281; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2639C>T p.T880M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs782792150; called by mutect2, varscan2
- GTPBP2 | c.183dup p.E62Rfs*3 | Frame Shift Ins (INS) | VAF 19/69 reads (28%) | catalogued as rs756968780; called by mutect2, pindel, varscan2
- GZF1 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454072446, COSV100582481; called by muse, mutect2, varscan2
- H2BC18 | c.73_75del p.K25del | In Frame Del (DEL) | VAF 31/133 reads (23%) | catalogued as rs782079686; called by pindel, varscan2
- HDAC4 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs868676793, COSV61859359; called by muse, mutect2, varscan2
- HEY2 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs761904411, COSV64239492; called by muse, mutect2, varscan2
- HHIP | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV56838358; called by mutect2, varscan2
- HLA-G | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.995); catalogued as COSV64405634; called by muse, mutect2, varscan2
- HNF4G | c.237del p.E80Kfs*10 (on ENST00000354370 / NM_001330561.2; = p.E127Kfs*10 on NM_004133.5) | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | catalogued as COSV100585066; called by mutect2, pindel, varscan2
- HSP90B1 | c.2400del p.D801Mfs*56 | Frame Shift Del (DEL) | VAF 31/65 reads (48%) | catalogued as COSV55354278; called by mutect2, pindel, varscan2
- HSPA12A | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.02); catalogued as rs782810800; called by muse, mutect2, varscan2
- HUWE1 | c.9550G>A p.E3184K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV53344835; called by muse, mutect2, varscan2
- HYAL3 | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1252877923; called by muse, mutect2, varscan2
- IFI44 | c.1332del p.K444Nfs*17 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as rs1309076306; called by mutect2, pindel, varscan2
- IGDCC3 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as COSV60078214; called by muse, mutect2, varscan2
- IL2RG | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs775704953, CM131925; called by muse, mutect2, varscan2
- INAVA | c.631_633del p.E211del | In Frame Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs1044974317; called by pindel, varscan2
- INF2 | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 72/85 reads (85%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs376139171; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- INTS11 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as rs759048878; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 43/125 reads (34%) | catalogued as rs761880048; called by mutect2, varscan2
- ITPKC | c.756dup p.Q253Tfs*4 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | catalogued as rs1484889842; called by mutect2, pindel, varscan2
- JPH3 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763624700; called by muse, mutect2, varscan2
- JPH3 | c.1060del p.L354Cfs*117 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as COSV52470301; called by mutect2, pindel, varscan2
- KAT6B | c.2737T>C p.Y913H | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs771809008, COSV54748579; called by muse, mutect2, varscan2
- KCNC3 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 106/135 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); catalogued as rs748735877, COSV65388920; called by muse, mutect2, varscan2
- KCNH4 | c.2390G>C p.G797A | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs770748876; called by muse, mutect2, varscan2
- KCNMA1 | c.2306del p.K769Sfs*17 (on ENST00000286628 / NM_001161352.2; = p.K711Sfs*17 on NM_002247.4) | Frame Shift Del (DEL) | VAF 33/118 reads (28%) | catalogued as rs771351714; called by mutect2, varscan2
- KCNMA1 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1389710406, COSV54234358, COSV54275501; called by muse, mutect2, varscan2
- KCNN1 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55838709; called by muse, mutect2, varscan2
- KCNS2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745687970, COSV99750942; called by muse, mutect2
- KCNT2 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV54073273; called by muse, varscan2
- KCTD13 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs973373938; called by muse, mutect2, varscan2
- KEAP1 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755995530; called by muse, mutect2, varscan2
- KIR3DL2 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 69/106 reads (65%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1176749891; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs756907493; called by mutect2, pindel, varscan2
- KLHL25 | c.1034C>T p.T345M | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs748049897, COSV61994115; called by muse, mutect2, varscan2
- KLHL30 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.449); catalogued as rs751497973, COSV59974285; called by muse, mutect2, varscan2
- KLHL36 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as rs770567702; called by muse, mutect2, varscan2
- KMT2A | c.1516A>G p.T506A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV63286946; called by muse, mutect2
- KRBA1 | c.1108T>C p.W370R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs777640969; called by muse, mutect2, varscan2
- KRT25 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs370147296; called by muse, mutect2, varscan2
- KRT35 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780375339, COSV55843911; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LMNB2 | c.1589C>T p.T530M | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771054060, COSV53113547; called by muse, mutect2, varscan2
- LRFN5 | c.472A>G p.N158D | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53250929, COSV99985198; called by muse, mutect2, varscan2
- LRIG3 | c.2588C>T p.T863M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs760319879, COSV57870388; called by muse, mutect2, varscan2
- LRP1 | c.6665C>T p.A2222V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs1362901174; called by muse, mutect2, varscan2
- LRP1 | c.8747G>A p.R2916H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as rs199825634; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 24/89 reads (27%) | catalogued as rs757410385; called by mutect2, varscan2
- LRRK2 | c.3820G>A p.D1274N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV54157296; called by muse, varscan2
- LZTR1 | c.1260+1G>A p.X420_splice | Splice Site (SNP) | VAF 25/59 reads (42%) | catalogued as rs143868364; called by muse, mutect2, varscan2
- MAEA | c.991G>A p.A331T (on ENST00000303400 / NM_001017405.3; = p.A290T on NM_005882.5) | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53265231; called by muse, mutect2, varscan2
- MAP1A | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774871578, COSV55809876; called by muse, varscan2
- MAP2K1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 52/64 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as rs1334665647, COSV61072123; called by muse, mutect2, varscan2
- MAP3K11 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as COSV100482652; called by muse, mutect2
- MAP4K4 | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV56324669; called by muse, mutect2, varscan2
- MAP7D1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs780310575, COSV60214922; called by muse, mutect2, varscan2
- MAST2 | c.3833A>G p.Q1278R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.271); catalogued as rs748102570; called by mutect2, varscan2
- MAST2 | c.4888C>A p.L1630I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as rs1159397742; called by muse, mutect2, varscan2
- MCTP2 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 108/158 reads (68%) | catalogued as rs200389318; called by muse, mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs746910913; called by mutect2, pindel, varscan2
- MEGF6 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373558942; called by muse, mutect2, varscan2
- METTL3 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs1302207202, COSV52970595; called by muse, mutect2, varscan2
- MICAL3 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs865849103; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 33/74 reads (45%) | catalogued as rs750307488; called by mutect2, varscan2
- MPZL1 | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as rs757960465; called by muse, mutect2, varscan2
- MST1 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs749446082; called by muse, mutect2, varscan2
- MTERF4 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs376613445; called by muse, mutect2, varscan2
- MTHFD2 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as rs751985540; called by muse, mutect2, varscan2
- MUC16 | c.42908A>G p.H14303R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1382795839; called by muse, mutect2, varscan2
- MUC17 | c.3085G>A p.G1029S | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1430962332; called by muse, mutect2, varscan2
- MUC5B | c.1492G>A p.G498S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368620070; called by muse, mutect2, varscan2
- MUC5B | c.17077G>A p.A5693T | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.351); catalogued as COSV71594420; called by muse, mutect2, varscan2
- MYH7B | c.1888G>A p.V630M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs571377722, COSV53420775; called by muse, mutect2, varscan2
- MYO18B | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs759388866, COSV100125849; called by muse, mutect2, varscan2
- MYO7A | c.3907A>G p.I1303V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.902); catalogued as rs762713039; called by muse, mutect2, varscan2
- NCKAP5 | c.3893G>A p.R1298H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545006757; called by muse, mutect2, varscan2
- NDUFB7 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs778158600; called by muse, mutect2, varscan2
- NFATC2 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.362); catalogued as COSV65353700, COSV65357899, COSV65359449; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 21/59 reads (36%) | catalogued as rs772439983; called by mutect2, varscan2
- NLRP12 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs747435135; called by muse, mutect2, varscan2
- NOC2L | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.264); catalogued as rs772311539; called by muse, mutect2, varscan2
- NOD2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs375201229; called by muse, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs759637346; called by mutect2, varscan2
- NOTCH1 | c.3880G>T p.E1294* | Nonsense Mutation (SNP) | VAF 72/85 reads (85%) | catalogued as COSV53031178; called by muse, mutect2, varscan2
- NPAS2 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs756916445; called by muse, mutect2, varscan2
- NRXN3 | c.2150G>A p.R717Q (on ENST00000335750 / NM_001330195.2; = p.R344Q on NM_004796.6) | Missense Mutation (SNP) | VAF 68/86 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59733958; called by muse, mutect2, varscan2
- NT5DC3 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs200566738; called by muse, mutect2, varscan2
- NUDCD3 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs1174300328, COSV58126345; called by muse, mutect2, varscan2
- NUFIP1 | c.494del p.K165Rfs*38 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs770344882; called by mutect2, varscan2
- OBSCN | c.12775G>A p.V4259M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as rs560506912; called by muse, mutect2, varscan2
- OR10A2 | c.867C>G p.S289R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104407501; called by muse, mutect2, varscan2
- OR2F1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231320; called by muse, mutect2, varscan2
- OR4C46 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as rs763006450; called by muse, mutect2, varscan2
- OR7D2 | c.321dup p.P108Sfs*14 | Frame Shift Ins (INS) | VAF 34/99 reads (34%) | catalogued as rs771661883; called by mutect2, pindel, varscan2
- OR8G1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs747754834; called by muse, mutect2, varscan2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs750679212; called by mutect2, varscan2
- PANK2 | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs747490823, COSV57255311; called by muse, mutect2, varscan2
- PATE1 | c.88+1G>A p.X30_splice | Splice Site (SNP) | VAF 18/34 reads (53%) | catalogued as rs186985607; called by muse, varscan2
- PCDH1 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs143703336; called by muse, mutect2, varscan2
- PCDH17 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.88); PolyPhen benign (0.182); catalogued as rs1380555470; called by muse, mutect2, varscan2
- PCDHB15 | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 120/182 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs1450297271, COSV50858134; called by muse, mutect2, varscan2
- PCDHGB4 | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as rs778996768; called by muse, mutect2, varscan2
- PGM5 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); catalogued as rs782232692, COSV67167563; called by muse, mutect2, varscan2
- PHLDB1 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs782496270; called by muse, mutect2, varscan2
- PHTF2 | c.1741C>T p.R581* (on ENST00000248550 / NM_001366089.1; = p.R543* on NM_020432.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs774201076; called by muse, mutect2, varscan2
- PIBF1 | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100411088; called by muse, mutect2, varscan2
- PILRB | c.242_244del p.F81del | In Frame Del (DEL) | VAF 17/79 reads (22%) | catalogued as rs1352037032; called by mutect2, pindel, varscan2
- PINK1 | c.1638G>T p.E546D | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV58630763; called by muse, mutect2, varscan2
- PIP4K2A | c.941dup p.D315Rfs*2 | Frame Shift Ins (INS) | VAF 14/20 reads (70%) | catalogued as rs755454854; called by mutect2, varscan2
- PKDREJ | c.3890G>A p.R1297H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs558518913; called by muse, mutect2, varscan2
- PKN3 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs754968087; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 33/68 reads (49%) | catalogued as rs745860467; called by mutect2, varscan2
- PLEKHG4 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 94/168 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763999027; called by muse, mutect2, varscan2
- PLXNB1 | c.536dup p.G180Wfs*22 | Frame Shift Ins (INS) | VAF 4/10 reads (40%) | catalogued as rs953293505; called by mutect2, varscan2
- POLR3B | c.2933G>A p.R978H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.671); catalogued as rs117293015, COSV57280942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLRMT | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs779119991; called by muse, mutect2
- POU3F2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs773452318, COSV60409331; called by muse, varscan2
- POU3F4 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as rs779536644, COSV64538294; called by muse, mutect2, varscan2
- POU5F2 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 20/27 reads (74%) | catalogued as rs1266630516, COSV67939807; called by muse, mutect2, varscan2
- PRAM1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs369144041, COSV99725231; called by muse, mutect2, varscan2
- PRDM10 | c.941del p.N314Mfs*8 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as COSV58805778; called by mutect2, pindel, varscan2
- PRG2 | c.590G>A p.C197Y | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100314934, COSV61293294; called by muse, mutect2
- PRNP | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751211144; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 18/25 reads (72%) | catalogued as rs753236928; called by mutect2, varscan2
- PTGDS | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs1408156338, COSV99811750; called by muse, mutect2, varscan2
- PTPRU | c.3370C>A p.R1124S | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114158; called by muse, mutect2, varscan2
- RAB2B | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773591681; called by muse, mutect2, varscan2
- RALYL | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs766785304, COSV72819337; called by muse, mutect2, varscan2
- RBPJL | c.1440C>A p.S480R | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.774); catalogued as COSV59214509; called by muse, mutect2, varscan2
- RELCH | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as rs1219251716, COSV99901965; called by muse, mutect2
- REV3L | c.4574C>G p.S1525C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62620046; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | catalogued as rs753959887; called by mutect2, varscan2
- RHBDL1 | c.881C>T p.A294V (on ENST00000219551 / NM_001318733.2; = p.A229V on NM_001278720.2) | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1321207294; called by muse, mutect2, varscan2
- RIC3 | c.722G>A p.R241H (on ENST00000309737 / NM_001206671.4; = p.R240H on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs575742410, COSV58305248; called by muse, mutect2, varscan2
- RIF1 | c.1414del p.S472Pfs*34 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | catalogued as COSV54616696; called by mutect2, pindel, varscan2
- RIOK1 | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53571242; called by muse, mutect2, varscan2
- RNF213 | c.14800C>A p.L4934I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1395269542, COSV100299589; called by muse, mutect2, varscan2
- RNF31 | c.2128C>T p.R710W | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1358080362, COSV53761355; called by muse, mutect2, varscan2
- RNF32 | c.199del p.T67Lfs*7 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | catalogued as rs771776056; called by mutect2, varscan2
- RNF43 | c.551T>C p.V184A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.297); catalogued as COSV101348520; called by muse, mutect2, varscan2
- RPL18A | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55830464; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs759252078; called by mutect2, varscan2
- RTP5 | c.674del p.P225Lfs*8 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as rs35989328, COSV100574622; called by mutect2, pindel, varscan2
- RYR1 | c.700C>A p.P234T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.089); catalogued as COSV62095851; called by muse, mutect2, varscan2
- SAAL1 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as rs1053424602, COSV55515803; called by muse, mutect2
- SBNO2 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs745855080; called by mutect2, varscan2
- SCUBE2 | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.905); catalogued as COSV100497121; called by muse, mutect2, varscan2
- SEC14L1 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs777176254, COSV66725750; called by muse, mutect2, varscan2
- SEC14L5 | c.1863dup p.S622Qfs*31 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | catalogued as rs764657044; called by mutect2, varscan2
- SF3B2 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs751434640; called by muse, mutect2, varscan2
- SIRT7 | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs771395879, COSV58710627, COSV58711491; called by muse, mutect2, varscan2
- SLC14A2 | c.2014G>A p.V672I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs145938404; called by muse, mutect2, varscan2
- SLC4A1AP | c.2354A>G p.D785G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762687983; called by muse, mutect2, varscan2
- SLC5A10 | c.1018C>T p.R340W (on ENST00000395645 / NM_001042450.4; = p.R356W on NM_152351.5) | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1257211033; called by muse, mutect2, varscan2
- SLCO6A1 | c.303T>A p.C101* | Nonsense Mutation (SNP) | VAF 22/32 reads (69%) | catalogued as COSV65815295; called by muse, mutect2, varscan2
- SLITRK4 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs782089060, COSV62023856; called by muse, mutect2, varscan2
- SNX19 | c.2355del p.D786Ifs*35 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as COSV99772910; called by mutect2, pindel, varscan2
- SNX20 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as rs902879100; called by muse, mutect2, varscan2
- SORBS1 | c.2924G>A p.R975Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs376968108; called by muse, mutect2, varscan2
- SORCS1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV53864467; called by muse, mutect2, varscan2
- SOWAHA | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746186847; called by muse, varscan2
- SPATA2L | c.643dup p.R215Pfs*37 | Frame Shift Ins (INS) | VAF 25/84 reads (30%) | catalogued as rs775005823; called by mutect2, varscan2
- SPHKAP | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as rs1484332491, COSV60876618; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 18/28 reads (64%) | catalogued as rs763130641; called by mutect2, varscan2
- SS18L1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs751601438; called by muse, mutect2, varscan2
- ST18 | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52483053, COSV52506573; called by muse, mutect2, varscan2
- STING1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs750561744; called by muse, mutect2, varscan2
- STK17A | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs770356144, COSV100082243; called by muse, mutect2, varscan2
- STMN4 | c.497G>A p.R166Q (on ENST00000265770 / NM_001283054.2; = p.R193Q on NM_030795.4) | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56110360; called by muse, mutect2, varscan2
- SUFU | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as rs199673680, COSV64015852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVEP1 | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); catalogued as rs185467075, COSV57035639; called by muse, mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYDE1 | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as rs771589119; called by muse, mutect2, varscan2
- TAAR9 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as rs765695223, COSV101453298; called by muse, mutect2, varscan2
- TBC1D9B | c.1280C>T p.S427L | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs770831310; called by muse, mutect2, varscan2
- TCF20 | c.3064C>T p.R1022W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1426050114, COSV59489707; called by muse, mutect2
- TCHP | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1179094854, COSV57165471; called by muse, mutect2, varscan2
- TCN2 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs770684965, COSV53191507; called by muse, mutect2, varscan2
- TENT4A | c.2335C>A p.H779N | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as rs748296365, COSV50094534; called by muse, mutect2
- TEP1 | c.5849G>T p.G1950V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52987675; called by muse, mutect2, varscan2
- TFRC | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs764730449, COSV100786570, COSV64057113; called by muse, mutect2
- TMEM245 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.994); catalogued as rs565558586, COSV65822387; called by muse, mutect2, varscan2
- TMEM53 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs150431791; called by muse, mutect2, varscan2
- TNR | c.1484del p.P495Lfs*42 | Frame Shift Del (DEL) | VAF 27/55 reads (49%) | catalogued as COSV54899554; called by mutect2, pindel, varscan2
- TNRC6C | c.4829C>T p.A1610V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs181099354, COSV56954709; called by muse, varscan2
- TNXB | c.7549C>T p.R2517C (on ENST00000647633; = p.R2270C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1454433703; called by muse, mutect2
- TOPBP1 | c.72del p.F24Lfs*7 | Frame Shift Del (DEL) | VAF 27/71 reads (38%) | catalogued as rs142462088; called by mutect2, pindel, varscan2
- TRAPPC12 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs547696140; called by muse, mutect2, varscan2
- TRDN | c.916T>G p.S306A | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as COSV100524039; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 17/144 reads (12%) | catalogued as rs752676391; called by mutect2, varscan2
- TTF1 | c.668dup p.K224Efs*5 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs765042099; called by mutect2, varscan2
- TTN | c.23087C>T p.P7696L (on ENST00000591111; = p.P6769L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | PolyPhen probably damaging (0.999); catalogued as rs773761640, COSV100630660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3D | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as rs1287018700; called by muse, mutect2, varscan2
- TUBGCP6 | c.5271del p.P1759Lfs*33 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as rs1569107513, COSV50539277; called by mutect2, pindel, varscan2
- UBE2E1 | c.94_96del p.K32del | In Frame Del (DEL) | VAF 22/38 reads (58%) | catalogued as rs781155886; called by pindel, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 55/220 reads (25%) | catalogued as rs763652408; called by mutect2, varscan2
- UNC93B1 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs754100504, COSV57098392; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs767420916; called by mutect2, varscan2
- USP24 | c.3775G>A p.D1259N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as rs761278282, COSV53776408; called by muse, mutect2, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 35/83 reads (42%) | catalogued as rs761345427; called by mutect2, pindel, varscan2
- USP6NL | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1170913116; called by muse, mutect2, varscan2
- UTP14C | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs770374423, COSV73000651; called by muse, mutect2, varscan2
- VAX2 | c.719del p.P240Hfs*36 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | catalogued as rs782186760; called by mutect2, pindel, varscan2
- VPS13A | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 76/104 reads (73%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs756091546; called by muse, mutect2, varscan2
- WASF3 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as rs373519573, COSV100098630; called by muse, varscan2
- WDFY3 | c.6578G>A p.R2193H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs766567564, COSV55704574; called by muse, mutect2, varscan2
- WDR19 | c.1886_1888del p.N629del | In Frame Del (DEL) | VAF 8/75 reads (11%) | catalogued as rs1560514751; called by pindel, varscan2
- WWP2 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.353); catalogued as rs142617495; called by muse, mutect2, varscan2
- XIRP2 | c.9139C>T p.R3047C (on ENST00000628543; = p.R3222C on NM_152381.6) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765119236, COSV54694932; called by muse, mutect2
- XKR7 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.769); catalogued as rs781133344, COSV73813021, COSV73813122; called by muse, mutect2, varscan2
- ZBTB4 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.223); catalogued as rs770942130, COSV60980110; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs751577786; called by mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDHHC16 | c.916_918del p.K306del | In Frame Del (DEL) | VAF 14/57 reads (25%) | catalogued as rs756458996; called by pindel, varscan2
- ZEB2 | c.2287C>T p.P763S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57958810; called by muse, mutect2, varscan2
- ZFHX3 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs776155336, COSV51714648; called by muse, mutect2, varscan2
- ZNF300 | c.973T>C p.Y325H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as rs1237644506; called by muse, mutect2, varscan2
- ZNF317 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs1219049768; called by muse, mutect2
- ZNF407 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs747714506; called by muse, mutect2, varscan2
- ZNF41 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.5); PolyPhen benign (0.166); catalogued as rs555581955, COSV57441067; called by muse, mutect2, varscan2
- ZNF862 | c.811del p.D271Mfs*9 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs769847259; called by mutect2, pindel
- ZW10 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.488); catalogued as rs201149106, COSV52317750; called by muse, mutect2, varscan2
- ABCB1 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABHD16B | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2
- ACAT1 | c.167del p.L56* | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | called by mutect2, pindel, varscan2
- ACVR2A | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAD1 | c.1607A>G p.H536R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAM19 | c.578A>G p.Q193R | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRA3 | c.2191A>G p.T731A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ADIRF | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AMY2A | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 69/460 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- APOB | c.5315_5317del p.N1772del | In Frame Del (DEL) | VAF 6/61 reads (10%) | called by pindel, varscan2
- ARC | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGAP20 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ARHGAP35 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
- ARNTL | c.1420C>A p.P474T (on ENST00000403290 / NM_001297719.2; = p.P473T on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL1 | c.86T>C p.M29T | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2A2 | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ATP8B3 | c.1695G>T p.W565C | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BCL9L | c.3784C>G p.P1262A | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2
- BCL9L | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCO1 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BLVRA | c.702G>T p.K234N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- BRD9 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); called by muse, mutect2
- C9orf131 | c.1382dup p.N461Kfs*33 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- CASZ1 | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- CCDC33 | c.1561_1563del p.K521del | In Frame Del (DEL) | VAF 24/28 reads (86%) | called by mutect2, pindel, varscan2
- CCDC40 | c.1284G>C p.E428D | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CCNT1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCT7 | c.1111A>G p.T371A | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD163 | c.3194del p.F1065Sfs*7 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, pindel, varscan2
- CD200R1 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CD22 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK12 | c.2682_2685del p.N894Kfs*14 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by pindel, varscan2
- CDK19 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CDK8 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CELSR1 | c.1841del p.G614Afs*54 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | called by mutect2, pindel, varscan2
- CELSR2 | c.6642del p.V2215Wfs*26 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, varscan2
- CENPE | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | called by mutect2, pindel
- CHRND | c.314del p.P105Rfs*77 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- CLEC16A | c.2939C>T p.S980F | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CLECL1 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CLSTN1 | c.1897dup p.A633Gfs*37 (on ENST00000377298 / NM_001009566.3; = p.A623Gfs*37 on NM_014944.4) | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- CRMP1 | c.433T>C p.Y145H | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CRNKL1 | c.1318C>A p.L440M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- CSF3 | c.97del p.L33Wfs*16 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- CSMD3 | c.8448T>A p.H2816Q (on ENST00000297405 / NM_001363185.1; = p.H2647Q on NM_052900.3) | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CSPG4 | c.303_304del p.E101Dfs*5 | Frame Shift Del (DEL) | VAF 27/131 reads (21%) | called by pindel, varscan2
- CXCR2 | c.934del p.L312Sfs*18 | Frame Shift Del (DEL) | VAF 25/69 reads (36%) | called by mutect2, pindel, varscan2
- CYB561A3 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | c.1573del p.W525Gfs*? | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- DCC | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DDX19B | c.323_324del p.Y108Cfs*21 | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- DDX28 | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- DENND2C | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DENND4B | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DGCR6L | c.371A>T p.E124V | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DIDO1 | c.3163A>G p.T1055A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLC1 | c.2791G>A p.G931R (on ENST00000276297 / NM_001348081.2; = p.G494R on NM_006094.5) | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DLD | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG2 | c.290C>T p.S97F (on ENST00000650630 / NM_001351274.2; = p.S60F on NM_001142699.3) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- DMTN | c.281del p.P94Hfs*137 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- DNAH1 | c.5229G>T p.E1743D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC2 | c.590del p.N197Mfs*8 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, varscan2
- DOCK1 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- DOP1A | c.560del p.G187Vfs*21 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | called by mutect2, pindel, varscan2
- DUSP29 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DZIP1L | c.796dup p.E266Gfs*4 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- EEF2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EFNA1 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ELMO2 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- EML4 | c.2720A>G p.N907S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMSY | c.3357A>G p.I1119M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ENC1 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ENO1 | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA8 | c.590_591dup p.R198Sfs*22 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, varscan2
- ERBB4 | c.3912del p.N1305Ifs*57 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- ESCO1 | c.1316del p.L439* | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- ESRP2 | c.1908C>A p.N636K (on ENST00000565858 / NM_001365264.1; = p.N626K on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- EWSR1 | c.1367del p.G456Vfs*170 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- EXOSC8 | c.252T>A p.D84E | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- EYA1 | c.1349dup p.N450Kfs*2 | Frame Shift Ins (INS) | VAF 20/218 reads (9%) | called by mutect2, pindel
- FAF1 | c.429del p.G144Afs*13 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- FAM20B | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM234B | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- FAP | c.1352A>G p.Y451C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAT2 | c.7806_7807del p.P2603Gfs*8 | Frame Shift Del (DEL) | VAF 66/140 reads (47%) | called by pindel, varscan2
- FBXO15 | c.1187del p.N396Ifs*25 | Frame Shift Del (DEL) | VAF 24/52 reads (46%) | called by mutect2, pindel, varscan2
- FBXO47 | c.1304_1306del p.A435_N436delinsD | In Frame Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- FEZ1 | c.552_554del p.E186del | In Frame Del (DEL) | VAF 28/45 reads (62%) | called by pindel, varscan2
- FEZF2 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- FLT3 | c.167T>C p.V56A | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- FRY | c.1076T>C p.L359S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FSIP2 | c.17129del p.P5710Qfs*6 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- GAA | c.1690T>C p.F564L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GGA3 | c.2062_2064del p.E688del (on ENST00000537686 / NM_138619.4; = p.E655del on NM_014001.5) | In Frame Del (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- GLG1 | c.1234G>C p.G412R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- GOLPH3 | c.290dup p.L97Ffs*17 | Frame Shift Ins (INS) | VAF 19/114 reads (17%) | called by mutect2, pindel, varscan2
- GON4L | c.4283del p.P1428Qfs*70 (on ENST00000368331 / NM_001282860.2; = p.P1428Qfs*65 on NM_032292.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- GPAA1 | c.461_462del p.S154Yfs*34 | Frame Shift Del (DEL) | VAF 32/146 reads (22%) | called by pindel, varscan2
- GPN1 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR141 | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GPR142 | c.169A>G p.R57G | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRIN3 | c.1981G>T p.G661* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- GSR | c.899del p.K300Rfs*21 | Frame Shift Del (DEL) | VAF 17/28 reads (61%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.2766A>T p.Q922H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUF1 | c.1010T>C p.L337S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GYS2 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- H3C11 | c.361A>T p.M121L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- HACE1 | c.2416T>C p.Y806H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- HCCS | c.266A>T p.N89I | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HDAC9 | c.874T>C p.S292P | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEPHL1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- HPX | c.210del p.F70Lfs*16 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- HSD11B1 | c.446del p.V149Afs*2 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- IFIT5 | c.850T>C p.F284L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 106/142 reads (75%) | called by muse, mutect2, varscan2
- IPO5 | c.1457T>C p.V486A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- ITGA6 | c.681dup p.D228* | Frame Shift Ins (INS) | VAF 15/63 reads (24%) | called by mutect2, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, varscan2
- JKAMP | c.542T>C p.L181S (on ENST00000554271 / NM_001284201.1; = p.L167S on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- KALRN | c.8717G>C p.G2906A (on ENST00000360013 / NM_001024660.4; = p.G1209A on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KATNAL1 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- KBTBD2 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNA6 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KCNQ4 | c.320del p.L107Cfs*32 | Frame Shift Del (DEL) | VAF 58/119 reads (49%) | called by mutect2, pindel, varscan2
- KHDC3L | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- KIAA1109 | c.1982A>T p.D661V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- KIAA1549L | c.4870G>T p.A1624S (on ENST00000321505; = p.A1921S on NM_012194.3) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- KIF20B | c.4641T>G p.I1547M (on ENST00000371728 / NM_001284259.2; = p.I1507M on NM_016195.4) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KIF5C | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLF15 | c.659T>C p.L220S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- KNTC1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LGALS9 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LIG3 | c.1655del p.G552Afs*4 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- LMO7 | c.616A>C p.S206R (on ENST00000357063; = p.S221R on NM_005358.5) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LONP2 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- LPA | c.5801C>A p.A1934D | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- LRATD2 | c.463C>A p.L155M | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); called by muse, mutect2
- LRRK1 | c.874A>G p.T292A | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.4289A>G p.K1430R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- MADCAM1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MAGED1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MAOB | c.35del p.G12Afs*17 | Frame Shift Del (DEL) | VAF 19/34 reads (56%) | called by mutect2, pindel, varscan2
- MAP2 | c.4420del p.T1474Qfs*14 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- MAP3K2 | c.329_336del p.I110Kfs*17 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- MAP3K4 | c.258del p.S87Afs*6 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- MARCHF4 | c.205del p.Q69Sfs*90 | Frame Shift Del (DEL) | VAF 17/31 reads (55%) | called by mutect2, varscan2
- MARCO | c.835A>G p.K279E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- MBD1 | c.564_565del p.C188Wfs*13 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- MED17 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MET | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- MFSD14A | c.1370G>T p.R457M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MOV10 | c.2156G>A p.G719D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MPP2 | c.1196C>T p.P399L (on ENST00000461854 / NM_001278372.2; = p.P375L on NM_005374.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- MRTFB | c.2737C>G p.L913V (on ENST00000571589 / NM_001365412.2; = p.L863V on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MTHFS | c.118-42_118-2del p.X40_splice | Splice Site (DEL) | VAF 14/34 reads (41%) | called by pindel, varscan2
- MYBL1 | c.1259del p.N420Tfs*13 | Frame Shift Del (DEL) | VAF 50/203 reads (25%) | called by mutect2, varscan2
- MYH6 | c.3664_3666del p.E1222del | In Frame Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, varscan2
- MYH7B | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MYO1D | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NCKAP5 | c.5333A>C p.D1778A | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NCKAP5 | c.4631A>T p.N1544I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- NDUFS2 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFATC2IP | c.729A>T p.Q243H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFRKB | c.53G>T p.G18V (on ENST00000446488 / NM_001143835.2; = p.G31V on NM_006165.3) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFYA | c.562dup p.S188Ffs*74 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- NOS3 | c.2785_2787del p.L929del | In Frame Del (DEL) | VAF 18/77 reads (23%) | called by pindel, varscan2
- NOTCH1 | c.4559_4562del p.D1520Afs*59 | Frame Shift Del (DEL) | VAF 20/37 reads (54%) | called by mutect2, varscan2
- NRIP2 | c.232C>A p.H78N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NTAN1 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP35 | c.696del p.F232Lfs*6 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | called by mutect2, pindel, varscan2
- OR13G1 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- OR4A47 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5P2 | c.320A>T p.E107V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR5P2 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- P3H3 | c.833del p.G278Afs*42 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- PATL1 | c.478del p.Q160Rfs*33 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- PCDHB16 | c.1016A>G p.D339G | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB3 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGB2 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCNT | c.9196_9198del p.K3066del | In Frame Del (DEL) | VAF 27/41 reads (66%) | called by mutect2, pindel, varscan2
- PDE4D | c.2007del p.K669Nfs*7 (on ENST00000340635 / NM_001104631.2; = p.K533Nfs*7 on NM_006203.4) | Frame Shift Del (DEL) | VAF 30/55 reads (55%) | called by mutect2, pindel, varscan2
- PDE5A | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PDLIM7 | c.1295A>C p.Q432P | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PDZD2 | c.4273A>G p.T1425A | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PHF1 | c.1013del p.P338Lfs*39 (on ENST00000374516 / NM_024165.3; = p.P338Lfs*114 on NM_002636.5) | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel
- PHF12 | c.2467A>T p.M823L | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHF21B | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- PI4KA | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- PIP4P1 | c.728T>G p.I243S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- PKD1L1 | c.3033G>T p.E1011D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PLD2 | c.321del p.Q108Rfs*8 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- PLEC | c.1573T>C p.F525L (on ENST00000322810 / NM_201380.4; = p.F415L on NM_000445.5) | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLEKHG4B | c.1298C>T p.A433V (on ENST00000283426; = p.A789V on NM_052909.5) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PLEKHG4B | c.2948A>G p.D983G (on ENST00000283426; = p.D1339G on NM_052909.5) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLSCR1 | c.556_558del p.C186del | In Frame Del (DEL) | VAF 13/81 reads (16%) | called by pindel, varscan2
- PLXNB3 | c.5625+1G>A p.X1875_splice | Splice Site (SNP) | VAF 22/27 reads (81%) | called by muse, mutect2, varscan2
- PML | c.1777C>A p.L593I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- POGLUT2 | c.731del p.K244Rfs*23 | Frame Shift Del (DEL) | VAF 35/75 reads (47%) | called by mutect2, pindel, varscan2
- POLR1C | c.592_594del p.L198del | In Frame Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- PPFIA4 | c.34del p.D12Tfs*18 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- PRKACA | c.547-2A>G p.X183_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- PRKCI | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PRKDC | c.3680del p.G1227Vfs*50 | Frame Shift Del (DEL) | VAF 48/234 reads (21%) | called by mutect2, pindel, varscan2
- PRRC2B | c.3129del p.M1044* | Frame Shift Del (DEL) | VAF 11/14 reads (79%) | called by mutect2, varscan2
- PSMD1 | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.3563del p.N1188Mfs*7 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- RALY | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RECQL | c.1841del p.K614Rfs*46 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- RHOBTB1 | c.1456G>T p.D486Y | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RIMBP2 | c.2590A>G p.M864V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RNF10 | c.221del p.N74Mfs*46 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- RPL13 | c.593del p.R198Kfs*60 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- RPS26 | c.131_132del p.I44Sfs*11 | Frame Shift Del (DEL) | VAF 35/108 reads (32%) | called by mutect2, pindel, varscan2
- RPS6KA5 | c.1342del p.S448Vfs*9 | Frame Shift Del (DEL) | VAF 57/113 reads (50%) | called by mutect2, pindel, varscan2
- RTN4 | c.2827T>C p.S943P | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); called by mutect2, varscan2
- RUNX1T1 | c.1337G>T p.W446L (on ENST00000265814 / NM_001198628.1; = p.W419L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCAF1 | c.3540del p.T1181Pfs*28 | Frame Shift Del (DEL) | VAF 7/10 reads (70%) | called by mutect2, varscan2
- SDS | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SELENOK | c.145del p.R49Efs*51 | Frame Shift Del (DEL) | VAF 13/26 reads (50%) | called by mutect2, pindel, varscan2
- SETDB1 | c.1096C>T p.R366* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- SF1 | c.836_837del p.C279Yfs*14 | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | called by pindel, varscan2
- SF3B3 | c.1799A>T p.Q600L | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC2A6 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC6A13 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SMARCAL1 | c.1594_1596del p.L532del | In Frame Del (DEL) | VAF 24/64 reads (38%) | called by pindel, varscan2
- SMARCD2 | c.1054T>C p.Y352H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SNX25 | c.1221del p.K407Nfs*6 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- SOCS5 | c.799A>G p.R267G | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SORBS2 | c.2543A>G p.D848G (on ENST00000284776 / NM_021069.5; = p.D414G on NM_003603.6) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- SP2 | c.1199del p.K400Sfs*25 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- SPATA5 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- SPEG | c.3419A>T p.N1140I | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SQLE | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SRPK1 | c.904dup p.R302Kfs*13 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- SRRM2 | c.1566G>T p.W522C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SVEP1 | c.4334T>C p.L1445P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TBX10 | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- TCF25 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TDRD1 | c.3230del p.N1077Ifs*4 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- TDRD3 | c.1813A>G p.I605V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- TDRD5 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TDRD6 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TECPR1 | c.2156del p.S719Tfs*24 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | called by mutect2, pindel, varscan2
- TENM2 | c.7040A>G p.Y2347C (on ENST00000518659 / NM_001122679.2; = p.Y2108C on NM_001080428.3) | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TET3 | c.4706C>T p.A1569V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TFAP2A | c.526_527del p.V176Nfs*2 (on ENST00000482890; = p.V168Nfs*2 on NM_001032280.3) | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- TIA1 | c.788C>T p.A263V (on ENST00000433529 / NM_001351511.1; = p.A252V on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TMEM132B | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TMEM266 | c.1486T>A p.F496I | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TMF1 | c.3237G>A p.M1079I | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- TNKS1BP1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TP73 | c.553_559del p.E185* | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- TPD52L2 | c.306_314+6del p.X102_splice | Splice Site (DEL) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- TRAF6 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TRIL | c.1181del p.P394Rfs*30 | Frame Shift Del (DEL) | VAF 22/89 reads (25%) | called by mutect2, pindel, varscan2
- TRIM33 | c.536T>G p.I179R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TRRAP | c.5768C>T p.A1923V (on ENST00000359863 / NM_001244580.1; = p.A1905V on NM_003496.3) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TSC2 | c.3784A>G p.K1262E | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TSGA10 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSPYL6 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- TTC21B | c.1490T>A p.L497Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTLL12 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.069); called by muse, varscan2
- TTN | c.62027C>T p.T20676I (on ENST00000591111; = p.T13252I on NM_003319.4) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTYH2 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- UBA6 | c.2095T>C p.C699R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBAP1 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR4 | c.10956G>T p.Q3652H | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- UPF1 | c.1748C>A p.P583H (on ENST00000599848 / NM_001297549.2; = p.P572H on NM_002911.4) | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- USP34 | c.7014_7015del p.N2338Kfs*6 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- USP43 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- USP54 | c.2959_2961del p.H987del | In Frame Del (DEL) | VAF 13/75 reads (17%) | called by pindel, varscan2
- USP7 | c.1758A>T p.E586D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCAM1 | c.1198C>A p.L400I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- VEGFC | c.579_580dup p.Q194Lfs*7 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | called by mutect2, varscan2
- VPS9D1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR7 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ZC3H3 | c.500dup p.R168Sfs*31 | Frame Shift Ins (INS) | VAF 19/175 reads (11%) | called by mutect2, pindel, varscan2
- ZMYND19 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- ZNF644 | c.3298_3300del p.R1100del | In Frame Del (DEL) | VAF 8/52 reads (15%) | called by pindel, varscan2
- ZNF721 | c.2452A>G p.I818V (on ENST00000338977; = p.I830V on NM_133474.4) | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF804B | c.321dup p.Q108Tfs*6 | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- ZNF878 | c.138del p.K46Nfs*18 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- A2M | c.1599C>T p.D533= | Silent (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- ABITRAM | c.189T>C p.I63= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- ABLIM1 | c.1849T>C p.L617= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- ACSM2A | c.1335A>C p.G445= (on ENST00000219054; = p.G366= on NM_001308169.2) | Silent (SNP) | VAF 53/82 reads (65%) | called by muse, mutect2, varscan2
- ADGRF3 | c.1545G>A p.A515= (on ENST00000311519 / NM_001145168.1; = p.A316= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs749656962, COSV61052814; called by muse, mutect2, varscan2
- AGPAT1 | c.264G>T p.G88= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- ALDOB | c.507C>T p.N169= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs746351347, COSV100878955; called by muse, mutect2, varscan2
- ALPP | c.921C>T p.D307= | Silent (SNP) | VAF 25/131 reads (19%) | called by muse, mutect2, varscan2
- ANAPC15 | c.54T>C p.F18= | Silent (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- ANKRD42 | c.573G>A p.T191= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs145591736; called by muse, mutect2, varscan2
- ARHGAP39 | c.1392G>A p.P464= | Silent (SNP) | VAF 23/203 reads (11%) | catalogued as rs758000654, COSV52770963; called by muse, mutect2, varscan2
- ARHGAP9 | c.735G>A p.P245= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs548695816, COSV62723257; called by muse, mutect2, varscan2
- ASB16 | c.423C>T p.V141= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs373603799; called by muse, mutect2, varscan2
- ATP11B | c.3486C>T p.N1162= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs372790774; called by muse, mutect2, varscan2
- AZIN2 | c.852C>T p.A284= | Silent (SNP) | VAF 35/90 reads (39%) | catalogued as rs1263903559; called by muse, mutect2, varscan2
- B3GNT4 | c.582G>A p.T194= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1346813982, COSV99928425; called by muse, mutect2, varscan2
- BCL9L | c.2025T>C p.R675= | Silent (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- BRPF1 | c.2508G>A p.R836= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1440713155, COSV57403811; called by muse, mutect2, varscan2
- BRWD3 | c.5343A>G p.R1781= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs1455210672; called by muse, mutect2, varscan2
- CALHM6 | c.153C>T p.Y51= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs541870005, COSV63991819; called by muse, varscan2
- CAP2 | c.411C>T p.S137= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs556554484, COSV57731102; called by muse, mutect2, varscan2
- CARMIL1 | c.1314T>C p.P438= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- CCDC8 | c.1362T>C p.A454= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- CCDC80 | c.177C>T p.R59= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs1330863475; called by muse, mutect2, varscan2
- CCDC82 | c.315C>T p.N105= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs774545821, COSV53592719; called by muse, mutect2, varscan2
- CCER1 | c.51T>C p.G17= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs761676354, COSV62647138; called by muse, mutect2, varscan2
- CCT7 | c.1392G>A p.L464= | Silent (SNP) | VAF 33/89 reads (37%) | called by muse, mutect2, varscan2
- CDK19 | c.606A>G p.P202= | Silent (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- CEP85L | c.321C>T p.S107= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV63822759; called by muse, mutect2, varscan2
- CLASP1 | c.3810A>G p.S1270= | Silent (SNP) | VAF 40/120 reads (33%) | called by muse, mutect2, varscan2
- CLIP2 | c.987C>T p.S329= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs199730295, COSV56286992; called by muse, mutect2, varscan2
- COL12A1 | c.6378C>T p.D2126= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs371734128; called by muse, mutect2, varscan2
- CORO1A | c.462C>T p.N154= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs762370414, COSV54632178; ClinVar: likely benign; called by muse, mutect2, varscan2
- COX10 | c.912G>A p.T304= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as rs762702842; called by muse, mutect2, varscan2
- CREB3 | c.234C>T p.D78= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- CSMD3 | c.4581G>A p.A1527= (on ENST00000297405 / NM_001363185.1; = p.A1423= on NM_052900.3) | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs563110439, COSV52314981; called by muse, mutect2, varscan2
- CSTF2T | c.1695G>A p.G565= | Silent (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- CTDP1 | c.1407C>T p.S469= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs973830692; called by muse, mutect2
- CYP4F3 | c.1176T>C p.H392= | Silent (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- DCC | c.1119T>C p.P373= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV100500356; called by muse, mutect2, varscan2
- DENND1C | c.810C>T p.H270= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs1398569031; called by muse, mutect2, varscan2
- DLG5 | c.3519G>A p.P1173= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs374398523; called by muse, mutect2, varscan2
- DLGAP1 | c.2106C>T p.A702= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs373443663; called by muse, varscan2
- DST | c.21420C>T p.G7140= (on ENST00000361203 / NM_001374722.1; = p.G4837= on NM_015548.5) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs545772116, COSV55002675; called by mutect2, varscan2
- DTX2 | c.1242C>T p.I414= | Silent (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2, varscan2
- EDIL3 | c.1362A>G p.R454= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV56908256; called by muse, mutect2, varscan2
- EEPD1 | c.864A>G p.T288= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs369820285; called by muse, mutect2, varscan2
- ELAVL2 | c.462T>C p.S154= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- EML4 | c.633T>C p.T211= | Silent (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- ENPP7 | c.1113T>C p.P371= | Silent (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- EPHA8 | c.960G>A p.P320= | Silent (SNP) | VAF 54/78 reads (69%) | catalogued as rs201432613, COSV51296721; called by muse, mutect2, varscan2
- EPPK1 | c.411C>T p.I137= | Silent (SNP) | VAF 46/159 reads (29%) | catalogued as rs549982161; called by muse, mutect2, varscan2
- ERAP1 | c.1365C>T p.D455= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs202098147; called by muse, mutect2, varscan2
- FAAH2 | c.240C>T p.D80= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs866870044, COSV66505447; ClinVar: likely benign; called by muse, mutect2, varscan2
- FASN | c.2694G>A p.T898= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs373471307, COSV100147595; ClinVar: likely benign; called by muse, mutect2, varscan2
- FCGBP | c.4290G>A p.P1430= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs781896995, COSV55429832; called by muse, mutect2, varscan2
- GALNTL6 | c.165G>A p.G55= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV72489362; called by muse, mutect2, varscan2
- GAN | c.1528T>C p.L510= | Silent (SNP) | VAF 86/212 reads (41%) | catalogued as COSV101634031; called by muse, mutect2, varscan2
- GGT7 | c.291G>A p.A97= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs781413741, COSV60541525; called by muse, mutect2, varscan2
- GLI3 | c.798C>T p.I266= | Silent (SNP) | VAF 36/100 reads (36%) | called by muse, mutect2, varscan2
- GPD2 | c.855T>C p.C285= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- GRIP1 | c.84C>T p.S28= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- HDAC4 | c.1695C>T p.S565= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as rs141268656; called by muse, mutect2, varscan2
- HELZ2 | c.4560G>A p.A1520= (on ENST00000467148 / NM_001037335.2; = p.A951= on NM_033405.3) | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs749599121, COSV101427611, COSV71295383; called by muse, mutect2, varscan2
- HNF1A | c.1611G>A p.T537= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs199511735, CD083317, COSV56566389; called by muse, mutect2, varscan2
- HNRNPK | c.999C>T p.Y333= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs774149530, COSV61090146; called by muse, mutect2, varscan2
- HOXB3 | c.948C>T p.G316= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs1349534576; called by muse, mutect2, varscan2
- HRNR | c.6126C>T p.H2042= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs773303607, COSV100913784, COSV100914038; called by muse, mutect2, varscan2
- HTR1B | c.885C>T p.S295= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs777408306, COSV64051429, COSV64051577; called by muse, mutect2, varscan2
- HTR1E | c.1083C>T p.C361= | Silent (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- ICAM5 | c.1080G>A p.A360= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV55747442; called by muse, mutect2, varscan2
- IGDCC4 | c.471C>T p.N157= | Silent (SNP) | VAF 28/35 reads (80%) | catalogued as rs777293264, COSV61535200; called by muse, mutect2, varscan2
- IQCA1 | c.2205G>A p.A735= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs377472762; called by muse, mutect2, varscan2
- IRF9 | c.390A>G p.P130= | Silent (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- JAK2 | c.397C>A p.R133= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- KCNC2 | c.603C>T p.P201= | Silent (SNP) | VAF 75/132 reads (57%) | called by muse, mutect2, varscan2
- KCNMB4 | c.603G>A p.A201= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs765167113, COSV50691150; called by muse, mutect2, varscan2
- KHDC4 | c.81C>A p.L27= | Silent (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- KLHL20 | c.264C>A p.A88= | Silent (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- KRT1 | c.369C>T p.G123= | Silent (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- KRTAP24-1 | c.183C>T p.C61= | Silent (SNP) | VAF 35/51 reads (69%) | catalogued as COSV104414029, COSV61089284, COSV61089856; called by muse, mutect2, varscan2
- LAMA1 | c.6477T>C p.G2159= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- LDHD | c.885C>T p.P295= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1370060885; called by muse, mutect2, varscan2
- LONP2 | c.2037C>T p.G679= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs768589313, COSV53522296; called by muse, mutect2, varscan2
- LRRC75B | c.375G>A p.S125= | Silent (SNP) | VAF 49/118 reads (42%) | catalogued as rs776835009, COSV50644861; called by muse, mutect2, varscan2
- LRRTM1 | c.129C>T p.C43= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- MAP3K19 | c.144C>T p.F48= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs749805940, COSV59636777; called by muse, mutect2, varscan2
- MAP9 | c.1035A>C p.A345= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs776150288; called by muse, mutect2, varscan2
- MAVS | c.999T>C p.P333= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs374618610; called by muse, mutect2, varscan2
- MED13L | c.5307A>G p.K1769= | Silent (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- MMP9 | c.672C>T p.N224= | Silent (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- MTMR7 | c.1401G>A p.R467= | Silent (SNP) | VAF 39/56 reads (70%) | called by muse, mutect2, varscan2
- MTSS2 | c.1002C>T p.D334= | Silent (SNP) | VAF 107/221 reads (48%) | catalogued as rs769290285, COSV58697752; called by muse, mutect2, varscan2
- MUSK | c.453A>G p.S151= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs373961420; called by muse, mutect2, varscan2
97 further variants in this file (0 protein-altering or splice-affecting, 85 silent, 12 other) are not listed here.
